Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A9V1, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A9V1-01A (Primary Tumor).

[page 1 of 2]
(MM/DD/YYYY)

ICD-O-3

Adenocarcinoma, mucinous
endocervical type 8482/3

Site: Cervix NOS C53.9

9/3/14

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

1- "Biopsy of uterine cervix":

Endocervical adenocarcinoma.

Per TSS dx discrepancy form, TCGA tumor
is INVASIVE mucinous adenocarcinoma of endocervical type.

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form

V9.04

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Endocervical adenocarcinoma	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Invasive mucinous adenocarcinoma of endocervical type	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Case was reviewed based on the top slide to be sent to BCR.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file f65df0ee-f035-4da8-b76c-ccc3fdfe090d (TCGA-VS-A9V1.BC3B49BB-004C-4079-B1A2-97B74891BFD6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).